RC case RC-B55B — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/96e6bdbf-e3a1-4a40-af8f-eb22079f7523

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1932; Vital status: Dead; Days to death: 792 days (2.2 years); Year of death: 2004; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (2)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Lymph nodes of head, face and neck; Classification of tumor: primary; Age at diagnosis: 69.8 years (25,500 days); Year of diagnosis: 2002; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Night Sweats / Other; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Cervical / Lymph Node, Hilar / Lymph Node, Iliac-External / Lymph Node, Inguinal / Lymph Node, Mediastinal / Lymph Node, Supraclavicular / Bone marrow.
   Pathology details: Bone marrow malignant cells: No; Greatest tumor dimension: 4.7 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Mitoxantrone + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CNOP; Days to treatment start: 9 days; Days to treatment end: 110 days; Number of cycles: 6; Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: First Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Subsequent primary (histology not recorded by GDC). Age at diagnosis: 71.5 years (26,114 days); Days to diagnosis: 614 days (1.7 years).

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Day 777 (end of treatment course 1): Imaging type: PET; Imaging result: Negative.

Molecular and laboratory tests
- Lactate Dehydrogenase 603 U/L [Blood test normal range upper: 618].
- Epstein-Barr Virus (ISH): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Hypertension / Hypothyroidism.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Initial Diagnosis; Weight: 68.7 kg; Height: 167 cm; BMI: 24.6.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Esophageal Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B55B-NM1-A: Tissue type: Normal; Specimen type: Bone Marrow Components NOS; Preservation method: Frozen.
- Sample RC-B55B-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B55B-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 90; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 70; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
